CCDI case PBCSWM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/c3e24fd4-e77d-418c-abb1-c23abfa148f2

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 14.4 years (5,248 days).

Biospecimens (3 samples)
- Sample 0DYNMH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYNN2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYNNW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
